TCGA case TCGA-L5-A8NG — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81be56da-bea2-426b-9576-950a909cc153

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 77.3 years (28,219 days); Year of diagnosis: 2001; Method of diagnosis: Biopsy; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: GX; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,094 days (3.0 years); Cancer detection method: Symptomatic; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 1; Lymph nodes tested: 4.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: External ear; Laterality: Left; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,094 days (3.0 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Reflux treatment type: Medically Treated; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 81 kg; Height: 166 cm; BMI: 29.4.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 100; Tobacco smoking quit year: 1990; Age at onset: 16.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-L5-A8NG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-L5-A8NG-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-L5-A8NG-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-L5-A8NG-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: michigan; Cancer procurement city: ann arbor; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Alcohol history documented: No; History reflux disease indicator: Yes; History barretts esophageal indicator: No; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Ear; Other malignancy histological type: Basal Cell Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: simple resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,094 days; disease-specific survival: no event (censored), 1,094 days; progression-free interval: no event (censored), 1,094 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-L5-A8NG-01A-11D-A37B-01): tumor purity 0.54, ploidy 1.78, whole-genome doublings 0.
